Somatic mutation profile of cancer-model specimen HCM-CSHL-0174-C22-85A (3D Organoid; aliquot HCM-CSHL-0174-C22-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0174-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-CSHL-0174-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49fff92f-886e-4b0e-ae37-b5ee9ac15662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0174-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0174-C22-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5993918-8bf7-4346-9507-3472ed1ffcfa

The open-access MAF lists 1,713 somatic variants for this specimen: 1,165 protein-altering or splice-affecting, 329 silent, 219 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 843, Silent 329, Frame Shift Del 196, Intron 116, Nonsense Mutation 40, Frame Shift Ins 37, 3'UTR 34, RNA 28, 5'UTR 27, Splice Site 22, In Frame Del 13, Splice Region 11.

Variants (750 of 1,713; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4615G>A p.E1539K (on ENST00000272895 / NM_173076.3; = p.E1221K on NM_015657.3) | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28940271, CM032168, COSV55968759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs104894742, CM960074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137852572, CM136027, CM920086, COSV65954067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 94/249 reads (38%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 82/193 reads (42%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GJA1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); catalogued as rs2227885, CM014191; ClinVar: likely benign / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KCNT1 | c.2743G>A p.A915T (on ENST00000488444; = p.A934T on NM_020822.3) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs397515403, CM129794, COSV53703025, COSV99706966; ClinVar: pathogenic; called by muse, mutect2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 77/114 reads (68%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTC | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs72554307, CM950870; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 88/186 reads (47%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 90/258 reads (35%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2
- SDHA | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as rs397514541, CM163827, COSV53767867, COSV53772354; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 133/187 reads (71%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912653, CM900212, COSV52764738, COSV52950153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 59/145 reads (41%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA4 | c.6365C>T p.A2122V | Missense Mutation (SNP) | VAF 191/522 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64671076, COSV64676839; called by muse, mutect2, varscan2
- ABCC10 | c.3835G>A p.V1279M (on ENST00000372530 / NM_001198934.2; = p.V1251M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762311029; called by muse, mutect2, varscan2
- ABCG8 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as rs1009122651, COSV53210230; called by muse, mutect2
- ABL1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191034511, COSV59325948; called by muse, mutect2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by muse, mutect2, varscan2
- ABR | c.1885C>T p.R629* (on ENST00000302538 / NM_021962.5; = p.R592* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 13/213 reads (6%) | catalogued as rs776303770; called by muse, mutect2
- AC008763.3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 67/179 reads (37%) | catalogued as rs1461187623, COSV100365374; called by muse, mutect2, varscan2
- AC011455.2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 64/617 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs377601567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACACA | c.5933G>A p.R1978H | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774579864; called by muse, mutect2, varscan2
- ACAN | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 179/408 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100719024; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2, varscan2
- ADAMTS17 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs993859963; called by muse, mutect2, varscan2
- ADAMTS6 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.41); catalogued as rs143194045; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRD1 | c.1254C>T p.H418= | Splice Region (SNP) | VAF 17/316 reads (5%) | catalogued as COSV55444394, COSV55457718; called by muse, mutect2
- ADGRE1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs753846792; called by muse, mutect2, varscan2
- ADGRL1 | c.3419G>A p.R1140H (on ENST00000340736 / NM_001008701.3; = p.R1135H on NM_014921.5) | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs776587952; called by muse, mutect2, varscan2
- AFF2 | c.2513A>G p.Q838R | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs1557287421; called by muse, mutect2, varscan2
- AFF2 | c.3110G>A p.S1037N | Missense Mutation (SNP) | VAF 238/515 reads (46%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as COSV53979732; called by muse, mutect2, varscan2
- AFF3 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57865960; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 78/170 reads (46%) | catalogued as COSV58317085; called by mutect2, varscan2
- AGBL1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376945285; called by muse, mutect2, varscan2
- AGGF1 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 78/176 reads (44%) | catalogued as rs758213462, COSV57227705; called by muse, varscan2
- AGO1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1385910631, COSV64594759; called by muse, mutect2, varscan2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, varscan2
- AKAP12 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as COSV53583612; called by muse, mutect2, varscan2
- AL031777.2 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 142/370 reads (38%) | catalogued as rs773584959; called by pindel, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 87/231 reads (38%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- AMPD2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 202/494 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56648847; called by muse, mutect2, varscan2
- AMPD3 | c.1686G>A p.M562I (on ENST00000396553 / NM_001025389.2; = p.M571I on NM_000480.3) | Missense Mutation (SNP) | VAF 246/492 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs372507080; called by muse, mutect2
- ANK1 | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.394); catalogued as rs781061339; called by muse, mutect2
- ANKRD17 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745621090, COSV58225617; called by muse, mutect2, varscan2
- ANO1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV60290126; called by muse, mutect2, varscan2
- AP4E1 | c.1064del p.L355* | Frame Shift Del (DEL) | VAF 68/192 reads (35%) | catalogued as rs1357583521; called by mutect2, pindel, varscan2
- APBB1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1420119374; called by muse, mutect2, varscan2
- APOE | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 241/487 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as CM111115, COSV52985125; called by muse, mutect2, varscan2
- APOOL | c.595del p.T199Lfs*3 | Frame Shift Del (DEL) | VAF 66/156 reads (42%) | catalogued as rs1293508812; called by mutect2, pindel, varscan2
- AQR | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780179363, COSV99333261; called by muse, mutect2, varscan2
- ARAP1 | c.1514G>A p.R505H (on ENST00000393609 / NM_001040118.2; = p.R260H on NM_015242.4) | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs777692919; called by muse, mutect2, varscan2
- ARHGAP21 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs530533376, COSV57604133; called by muse, mutect2, varscan2
- ARHGEF10L | c.432C>T p.P144= | Splice Region (SNP) | VAF 86/139 reads (62%) | catalogued as rs755364404, COSV63422614; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 60/124 reads (48%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1A | c.3820G>T p.G1274* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as COSV61371474; called by muse, mutect2, varscan2
- ARRB2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV52617001; called by muse, mutect2, varscan2
- ARSD | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.42); catalogued as rs774734859; called by muse, mutect2, varscan2
- ARSI | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60817065, COSV60817994; called by muse, mutect2, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | catalogued as rs770804405; called by mutect2, varscan2
- ASTN1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs745514951, COSV56065176, COSV56066780; called by muse, mutect2, varscan2
- ASTN1 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs774847597, COSV99920531; called by muse, varscan2
- ASXL2 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.946); catalogued as rs1307171996; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 41/105 reads (39%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP2A1 | c.2267_2269del p.N756del | In Frame Del (DEL) | VAF 172/516 reads (33%) | catalogued as rs766141393; called by pindel, varscan2
- ATP4A | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs375401694; called by muse, mutect2, varscan2
- BAG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.707); catalogued as rs770041398, COSV54861341, COSV54862630; called by muse, mutect2, varscan2
- BAIAP3 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.135); catalogued as rs770815658; called by muse, mutect2, varscan2
- BAZ1B | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 133/246 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59991019, COSV59993745; called by muse, mutect2, varscan2
- BCL6 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs1178677766, COSV99216165; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 61/158 reads (39%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCR | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1244976763; called by muse, mutect2, varscan2
- BEND3 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147116683; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 76/84 reads (90%) | catalogued as rs755506199; called by mutect2, varscan2
- BMS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748277670; called by muse, mutect2, varscan2
- BTK | c.215del p.N72Ifs*49 | Frame Shift Del (DEL) | VAF 159/496 reads (32%) | catalogued as CD087030, CD982512, CX984150; called by pindel, varscan2
- C16orf46 | c.412del p.Q138Rfs*66 | Frame Shift Del (DEL) | VAF 70/151 reads (46%) | catalogued as rs1567574033; called by mutect2, pindel, varscan2
- C1QTNF2 | c.218G>A p.R73Q (on ENST00000393975; = p.R28Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375483575; called by muse, mutect2, varscan2
- C21orf58 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs375276205; called by muse, mutect2, varscan2
- C2CD5 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.073); catalogued as rs151297499; called by muse, mutect2, varscan2
- CACNA1C | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.97); catalogued as rs1231323774; called by muse, mutect2
- CACNA1E | c.2705del p.G902Efs*5 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as COSV62382319; called by mutect2, pindel, varscan2
- CACNA1E | c.4991C>T p.A1664V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62430270; called by muse, mutect2, varscan2
- CAGE1 | c.2238del p.A747Pfs*9 (on ENST00000512086; = p.A611Pfs*9 on NM_205864.3) | Frame Shift Del (DEL) | VAF 76/199 reads (38%) | catalogued as COSV57081154; called by mutect2, pindel, varscan2
- CAMK1G | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs763192311; called by muse, mutect2
- CAMSAP3 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs185048709; called by muse, mutect2, varscan2
- CAPG | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 124/258 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs756006551, COSV99809333; called by muse, mutect2, varscan2
- CARM1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV53404227; called by muse, mutect2, varscan2
- CARMIL1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 105/245 reads (43%) | catalogued as rs1385108756, COSV61523112; called by muse, mutect2, varscan2
- CBARP | c.1067G>T p.R356L (on ENST00000382477; = p.R336L on NM_152769.3) | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53071806; called by muse, mutect2, varscan2
- CCDC136 | c.2066A>G p.Q689R | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99923222; called by muse, mutect2, varscan2
- CCDC168 | c.8926G>A p.A2976T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV59426418; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 56/124 reads (45%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC38 | c.355A>G p.R119G | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs145671956; called by muse, mutect2, varscan2
- CCDC88C | c.1803G>T p.E601D | Missense Mutation (SNP) | VAF 50/545 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV66241843; called by muse, mutect2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2, varscan2
- CCNJ | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs1488931381, COSV99796155; called by muse, mutect2
- CCS | c.285dup p.P96Afs*16 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs759691599; called by mutect2, varscan2
- CCT7 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs11544996; called by muse, mutect2, varscan2
- CD3E | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 249/547 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.123); catalogued as rs200087808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 171/419 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 67/160 reads (42%) | catalogued as rs779465056; called by mutect2, pindel, varscan2
- CDADC1 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); catalogued as rs149569821; called by muse, mutect2, varscan2
- CDC42BPG | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360476699; called by muse, mutect2
- CDH22 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1303483268, COSV64837485; called by muse, mutect2, varscan2
- CDK13 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs934764468, COSV51706512; called by muse, mutect2, varscan2
- CDYL | c.1192G>A p.V398I (on ENST00000328908 / NM_001368125.1; = p.V344I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs761722419, COSV59361810; called by muse, mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CERS6 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV59830504; called by muse, mutect2, varscan2
- CES5A | c.1005T>G p.I335M | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs866504798; called by muse, mutect2, varscan2
- CFAP161 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as rs372365773; called by mutect2, varscan2
- CFAP74 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs374625283, COSV99574774; called by muse, mutect2
- CFAP94 | c.1798G>A p.A600T (on ENST00000320267 / NM_001352064.2; = p.A606T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57230325; called by muse, mutect2, varscan2
- CGB5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1201663825; called by mutect2, varscan2
- CHD5 | c.5660del p.P1887Rfs*14 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | catalogued as rs928253921; called by mutect2, varscan2
- CHPF | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs776863694, COSV60537310; called by muse, mutect2, varscan2
- CHRM4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 166/367 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759941649, COSV63126375; called by muse, mutect2, varscan2
- CHRNA6 | c.494del p.F165Sfs*10 | Frame Shift Del (DEL) | VAF 49/156 reads (31%) | catalogued as rs774808608; called by mutect2, pindel, varscan2
- CIP2A | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754404518; called by muse, mutect2, varscan2
- CLASP1 | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs1209432824; called by muse, mutect2
- CLASP2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as rs368159421; called by muse, mutect2, varscan2
- CLEC16A | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as rs866629699; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 47/114 reads (41%) | catalogued as rs369752219; called by mutect2, varscan2
- CMIP | c.1555C>G p.R519G (on ENST00000537098 / NM_198390.2; = p.R425G on NM_030629.3) | Missense Mutation (SNP) | VAF 247/528 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67698609; called by muse, mutect2, varscan2
- CNGA2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756195328, COSV100323969; called by muse, mutect2, varscan2
- CNNM1 | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 110/189 reads (58%) | catalogued as rs376631525; called by muse, mutect2, varscan2
- CNR1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs753881911; called by muse, mutect2
- COL1A1 | c.3540del p.G1181Afs*58 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | catalogued as CD1110814; called by mutect2, pindel, varscan2
- COL20A1 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs748113437, COSV58914315; called by muse, mutect2, varscan2
- COL6A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs753966526, COSV55104699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV53731656; called by muse, mutect2, varscan2
- CORO6 | c.1194del p.K399Sfs*96 | Frame Shift Del (DEL) | VAF 108/255 reads (42%) | catalogued as rs756429595; called by mutect2, pindel, varscan2
- CRNKL1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 48/49 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781077783, COSV99842955; called by muse, mutect2, varscan2
- CSAG2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 18/652 reads (3%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.006); catalogued as rs1480136931; called by muse, mutect2
- CSMD1 | c.9308C>T p.P3103L (on ENST00000520002; = p.P3102L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs984147998, COSV59277615; called by muse, mutect2
- CSMD3 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.123); catalogued as COSV99847717; called by muse, mutect2
- CSPP1 | c.1102C>T p.P368S (on ENST00000676605; = p.P327S on NM_024790.6) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV51580378; called by muse, mutect2, varscan2
- CT47B1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 254/545 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746190277, COSV100989010; called by muse, mutect2, varscan2
- CTBP1 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1388198458; called by muse, mutect2, varscan2
- CTNNA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 142/142 reads (100%) | catalogued as COSV57077911; called by muse, mutect2, varscan2
- CWH43 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 118/214 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1415857655, COSV99893165; called by muse, mutect2, varscan2
- CYBRD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs150572307; called by muse, mutect2, varscan2
- CYP2C8 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1313975039; called by muse, mutect2
- CYP2C9 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV53247604; called by muse, mutect2, varscan2
- CYS1 | c.475T>G p.*159Gext*29 | Nonstop Mutation (SNP) | VAF 76/170 reads (45%) | catalogued as rs774180325; called by muse, mutect2, varscan2
- DAPK2 | c.1033-7del | Splice Region (DEL) | VAF 30/35 reads (86%) | catalogued as rs753638020; called by mutect2, varscan2
- DENND1B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs779126393; called by muse, mutect2, varscan2
- DEPDC5 | c.2968G>A p.A990T (on ENST00000400246; = p.A1059T on NM_014662.5) | Missense Mutation (SNP) | VAF 201/367 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.153); catalogued as rs763158282, COSV99835501; called by muse, mutect2, varscan2
- DICER1 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 46/500 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs139346443; ClinVar: uncertain significance; called by muse, mutect2
- DIP2A | c.3706G>A p.V1236I | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs761203268, COSV59481294; called by muse, mutect2, varscan2
- DIP2C | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as rs775934914, COSV99792008; called by muse, varscan2
- DLL4 | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1404800749, COSV99990087; called by muse, mutect2, varscan2
- DLST | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1025995190, COSV53168045; called by muse, mutect2, varscan2
- DMC1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 33/465 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477150457, COSV53260264; called by muse, mutect2
- DNAH10 | c.3172C>T p.R1058* (on ENST00000409039; = p.R997* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 103/182 reads (57%) | catalogued as rs1449530904, COSV68991805; called by muse, mutect2, varscan2
- DNAJC10 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as rs768125706; called by muse, mutect2, varscan2
- DNHD1 | c.10298G>A p.R3433H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182015408; called by muse, mutect2, varscan2
- DNMT3B | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 24/496 reads (5%) | catalogued as CM164014, COSV52417440; called by muse, mutect2
- DOCK8 | c.5059G>A p.V1687M | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs767895149, COSV101209866; called by muse, mutect2, varscan2
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2, varscan2
- DOK7 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs767832304; called by muse, mutect2
- DPF2 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 135/318 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV52891484; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2
- DSCAML1 | c.754G>A p.A252T (on ENST00000321322; = p.A192T on NM_020693.4) | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs142110596, COSV58389573; called by muse, mutect2, varscan2
- DVL1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs149964617; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 41/91 reads (45%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECT2 | c.2507del p.K836Rfs*21 (on ENST00000392692 / NM_001349098.2; = p.K805Rfs*21 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/121 reads (45%) | catalogued as rs1560030630; called by mutect2, pindel, varscan2
- EIF3CL | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV66534056; called by muse, mutect2, varscan2
- EIF4A3 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs755596816; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 62/114 reads (54%) | catalogued as rs770453803; called by mutect2, varscan2
- EP400 | c.6545C>T p.A2182V | Missense Mutation (SNP) | VAF 119/233 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs565827189; called by muse, varscan2
- EPHA3 | c.2539A>G p.M847V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as rs1315561019; called by muse, mutect2, varscan2
- EPRS1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448727059; called by muse, mutect2, varscan2
- ERBIN | c.3389G>A p.R1130Q | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144581883; called by muse, mutect2, varscan2
- ERICH3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs865943394, COSV58604950; called by muse, mutect2, varscan2
- FAF2 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99990456; called by muse, mutect2, varscan2
- FAM149A | c.2095C>T p.R699* (on ENST00000356371 / NM_001367768.2; = p.R408* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as rs766661467, COSV57030946; called by muse, mutect2, varscan2
- FAM184A | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs775749960; called by muse, mutect2, varscan2
- FAM3D | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 176/177 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs368973392; called by muse, mutect2, varscan2
- FAM83D | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 172/316 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757902095; called by muse, mutect2, varscan2
- FAM91A1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 125/236 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1012721253, COSV58236363; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs757443519; called by mutect2, varscan2
- FASN | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1009899437; called by muse, mutect2, varscan2
- FASTKD1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs149861551; called by muse, mutect2, varscan2
- FAT4 | c.14389C>T p.L4797F | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs267600018, COSV58703970; called by muse, mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 12/93 reads (13%) | catalogued as rs755836480; called by mutect2, varscan2
- FEM1B | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60988378; called by muse, mutect2
- FGD2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780657307, COSV51464056; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/126 reads (48%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 52/126 reads (41%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FKRP | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764621521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.2836G>T p.G946C | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61051609; called by muse, mutect2, varscan2
- FLNC | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 179/396 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1417082178, COSV57949813; called by muse, mutect2, varscan2
- FLOT2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774018833; called by muse, mutect2, varscan2
- FLT3 | c.2729A>G p.Q910R | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as rs1318196723; called by muse, mutect2, varscan2
- FLYWCH1 | c.1907G>A p.R636Q (on ENST00000253928 / NM_001308068.2; = p.R635Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs777293183; called by muse, mutect2, varscan2
- FNIP2 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314321471, COSV52439130; called by muse, mutect2, varscan2
- FOXC1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 395/802 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 190/538 reads (35%) | catalogued as COSV56761013; called by mutect2, pindel, varscan2
- FRZB | c.855del p.V286Lfs*6 | Frame Shift Del (DEL) | VAF 85/235 reads (36%) | catalogued as rs1366062663; called by mutect2, pindel, varscan2
- G6PD | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 292/601 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as CM920286, COSV63703327; called by muse, mutect2, varscan2
- GABPB2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770162643, COSV104425990; called by muse, mutect2
- GALNT3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as rs376963628; called by muse, mutect2, varscan2
- GATA3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 40/698 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511800, COSV60517310; called by muse, mutect2
- GCAT | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs779625361; called by muse, mutect2
- GCNA | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as rs377512808; called by muse, mutect2
- GGTLC1 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 517/944 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs541165436, COSV99600652; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 69/136 reads (51%) | catalogued as rs763147690; called by mutect2, varscan2
- GIT1 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 179/340 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs769808064; called by muse, mutect2, varscan2
- GNB3 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV51831647; called by muse, mutect2, varscan2
- GNE | c.623G>A p.R208H (on ENST00000396594 / NM_001128227.3; = p.R177H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/95 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs772597073, COSV64951377; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GNPAT | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs767959114, COSV64152975; called by muse, mutect2, varscan2
- GP5 | c.1403del p.G468Vfs*43 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | catalogued as rs750921214; called by mutect2, pindel, varscan2
- GPKOW | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs782735883; called by muse, mutect2, varscan2
- GPR108 | c.1018G>A p.A340T (on ENST00000264080 / NM_001080452.1; = p.A98T on NM_020171.2) | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs371747238; called by muse, mutect2, varscan2
- GPR143 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs751622915, COSV66632596; called by muse, mutect2
- GPR179 | c.4108G>A p.E1370K (on ENST00000621958; = p.E1369K on NM_001004334.4) | Missense Mutation (SNP) | VAF 119/231 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs11872089; called by muse, mutect2, varscan2
- GRK2 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs752975715; called by muse, mutect2, varscan2
- HDLBP | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 66/594 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1486987244, COSV60493869; called by muse, mutect2
- HERC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs769145958, COSV71250686; called by muse, mutect2, varscan2
- HERC4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1164946098, COSV53268584; called by muse, mutect2, varscan2
- HIC1 | c.1811G>A p.R604H (on ENST00000322941 / NM_001098202.1; = p.R585H on NM_006497.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53964405; called by muse, mutect2, varscan2
- HIRA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54277074; called by muse, mutect2, varscan2
- HIRIP3 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs139557944; called by muse, mutect2, varscan2
- HIVEP2 | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 171/296 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs764073074; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 42/124 reads (34%) | catalogued as COSV50007394; called by muse, varscan2
- HMCN1 | c.11153del p.G3718Afs*6 | Frame Shift Del (DEL) | VAF 25/241 reads (10%) | catalogued as COSV54874338; called by mutect2, pindel, varscan2
- HNF4G | c.224C>T p.A75V (on ENST00000354370 / NM_001330561.2; = p.A122V on NM_004133.5) | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs770285159, COSV62972179; called by muse, mutect2, varscan2
- HRC | c.1269del p.R424Gfs*38 | Frame Shift Del (DEL) | VAF 111/201 reads (55%) | catalogued as COSV53255991; called by mutect2, varscan2
- HSPA1L | c.1314del p.V440Cfs*2 | Frame Shift Del (DEL) | VAF 164/412 reads (40%) | catalogued as COSV65149080; called by mutect2, pindel, varscan2
- HSPG2 | c.8212G>A p.V2738M | Missense Mutation (SNP) | VAF 188/326 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144862631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.1858T>C p.Y620H | Missense Mutation (SNP) | VAF 280/788 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928196274; called by muse, mutect2, varscan2
- HTR6 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367555533; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 86/187 reads (46%) | catalogued as rs747841314; called by mutect2, varscan2
- IFIT1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs146515241; called by muse, mutect2
- IGDCC4 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61538419; called by muse, mutect2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 124/292 reads (42%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGHV4-39 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 520/527 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs587685263; called by muse, mutect2, varscan2
- IGKV1-17 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 143/514 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1435944291; called by muse, mutect2, varscan2
- IGSF9 | c.1253del p.P418Qfs*4 (on ENST00000368094 / NM_001135050.2; = p.P402Qfs*4 on NM_020789.4) | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs1384580209; called by mutect2, pindel, varscan2
- IMPDH1 | c.608G>A p.S203N (on ENST00000470772 / NM_001142573.2; = p.S289N on NM_000883.4) | Missense Mutation (SNP) | VAF 288/601 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100118624; called by muse, mutect2, varscan2
- INPPL1 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779810240; called by muse, mutect2, varscan2
- INTS1 | c.3478G>T p.A1160S | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV101247519; called by muse, mutect2, varscan2
- INTS1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67179428; called by muse, mutect2, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 56/199 reads (28%) | catalogued as rs1352150703; called by mutect2, varscan2
- INVS | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs529208660; called by muse, mutect2, varscan2
- IQCE | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); catalogued as rs201141275; called by muse, mutect2, varscan2
- IRF7 | c.212G>A p.R71H (on ENST00000397566; = p.R58H on NM_001572.5) | Missense Mutation (SNP) | VAF 121/245 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs766334448; called by muse, mutect2, varscan2
- IRGC | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54983350; called by muse, mutect2, varscan2
- IRX2 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as rs796424759; called by muse, mutect2, varscan2
- ISG15 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 208/369 reads (56%) | catalogued as rs200652935; called by muse, mutect2, varscan2
- ISLR2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 92/171 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as rs1198523188; called by muse, mutect2, varscan2
- ISLR2 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 146/268 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as COSV62303721; called by muse, mutect2, varscan2
- ITGAL | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs750373265, COSV63322312; called by muse, mutect2, varscan2
- ITGB7 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as rs1356768179; called by muse, mutect2, varscan2
- ITIH6 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs750304500, COSV54488247; called by muse, mutect2, varscan2
- KCNA1 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 265/662 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM940994; called by muse, varscan2
- KCND3 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56186032; called by muse, mutect2, varscan2
- KCNG4 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753628017; called by muse, mutect2, varscan2
- KCNH3 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs201670637; called by muse, mutect2
- KCNK2 | c.817G>A p.V273I (on ENST00000444842 / NM_001017425.3; = p.V258I on NM_014217.4) | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs367815630; called by muse, mutect2, varscan2
- KCNN2 | c.1693C>T p.R565W (on ENST00000264773; = p.R777W on NM_021614.4) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs79675198, COSV53283201; called by muse, mutect2, varscan2
- KCNQ2 | c.1793C>T p.A598V (on ENST00000359125 / NM_172107.4; = p.A570V on NM_004518.6) | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as rs746079131, COSV60549579; ClinVar: uncertain significance; called by muse, mutect2
- KCTD18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs543025211, COSV63344171; called by muse, mutect2, varscan2
- KCTD18 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243082924, COSV63344199; called by muse, mutect2, varscan2
- KCTD21 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs778118017, COSV60741135, COSV60741494, COSV60741878; called by muse, mutect2, varscan2
- KIAA0319L | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 99/160 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs770305152, COSV57848683; called by muse, mutect2, varscan2
- KIAA1671 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 246/428 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs1271381341; called by muse, mutect2, varscan2
- KIAA2026 | c.4717G>A p.V1573M | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198947; called by muse, mutect2, varscan2
- KIF14 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435446065, COSV100950704; called by muse, mutect2
- KIF18B | c.1178del p.G393Efs*91 (on ENST00000593135 / NM_001265577.2; = p.G393Efs*103 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 71/163 reads (44%) | catalogued as rs1347932473, COSV59271974, COSV59272099; called by mutect2, pindel, varscan2
- KIF1A | c.2344del p.R782Afs*30 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV57494105, COSV57504132; called by mutect2, pindel, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 111/286 reads (39%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs886054237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL20 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1337434730, COSV52940996; called by muse, mutect2, varscan2
- KLHL22 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1273833949, COSV61020365; called by muse, mutect2, varscan2
- KLHL40 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 111/112 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187688307, COSV99825551; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 56/149 reads (38%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.6895del p.R2299Gfs*26 | Frame Shift Del (DEL) | VAF 73/177 reads (41%) | catalogued as rs1568382485; called by mutect2, pindel, varscan2
- KMT2C | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 106/199 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs150747860; ClinVar: not provided; called by muse, mutect2, varscan2
- KNDC1 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs566345817, COSV58831384; called by muse, mutect2, varscan2
- KPNA2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs369989302; called by muse, mutect2, varscan2
- KRI1 | c.666G>A p.T222= | Splice Region (SNP) | VAF 39/65 reads (60%) | catalogued as rs776247947, COSV100469631; called by muse, mutect2, varscan2
- KRT10 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM973395; called by muse, mutect2, varscan2
- KRTAP10-4 | c.312del p.C105Afs*75 | Frame Shift Del (DEL) | VAF 38/401 reads (9%) | catalogued as COSV59979735; called by mutect2, varscan2
- KRTAP2-1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1435605987; called by muse, mutect2, varscan2
- KSR1 | c.437C>T p.T146M (on ENST00000644974 / NM_001367810.1; = p.T9M on NM_014238.2) | Missense Mutation (SNP) | VAF 107/267 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as rs761371576; called by muse, mutect2, varscan2
- L3MBTL4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 145/341 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV53123806; called by muse, mutect2, varscan2
- LAPTM4B | c.750_752del p.L251del (on ENST00000445593; = p.L160del on NM_018407.6) | In Frame Del (DEL) | VAF 39/147 reads (27%) | catalogued as rs777944332; called by pindel, varscan2
- LAPTM5 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 26/489 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs762845113, COSV99612501; called by muse, mutect2
- LCK | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777499240; called by muse, mutect2, varscan2
- LPCAT2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50896497; called by muse, mutect2, varscan2
- LRP1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520303; called by muse, varscan2
- LRRC38 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1200188907; called by muse, mutect2
- LRRTM3 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.088); catalogued as COSV63669719; called by muse, mutect2, varscan2
- LUZP2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV61208270; called by muse, mutect2, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 15/31 reads (48%) | catalogued as rs752439249; called by mutect2, varscan2
- MAN1A1 | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63784658; called by muse, mutect2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 47/68 reads (69%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K15 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100135161; called by muse, mutect2, varscan2
- MAPK14 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57696494; called by muse, mutect2, varscan2
- MAPT | c.1202C>T p.A401V (on ENST00000262410 / NM_001377265.1; = p.A326V on NM_016835.4) | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV52239842; called by muse, mutect2, varscan2
- MARK2 | c.1582C>T p.R528C (on ENST00000402010 / NM_001039469.2; = p.R494C on NM_017490.4) | Missense Mutation (SNP) | VAF 158/160 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs972173237, COSV59282370; called by muse, mutect2, varscan2
- MAST1 | c.3196C>A p.R1066S | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52243316; called by muse, mutect2, varscan2
- MAST4 | c.6599C>T p.P2200L (on ENST00000403625 / NM_001164664.2; = p.P2011L on NM_015183.3) | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs986498579, COSV104375397; called by muse, mutect2, varscan2
- MBNL1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 194/351 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as rs780538995, COSV56828467, COSV56836247; called by muse, mutect2, varscan2
- MBTD1 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64504345; called by muse, mutect2, varscan2
- MCF2L | c.2198G>A p.R733H (on ENST00000375608; = p.R701H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs774936427, COSV56175265; called by muse, mutect2, varscan2
- MCFD2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 223/500 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as rs1162286700, COSV60177920; called by muse, mutect2, varscan2
- MCTP2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs571941802, COSV59144810; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MED13L | c.5585A>G p.N1862S | Missense Mutation (SNP) | VAF 194/337 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1397464926; called by muse, mutect2, varscan2
- MEF2B | c.542-2A>G p.X181_splice | Splice Site (SNP) | VAF 44/88 reads (50%) | catalogued as COSV50766234; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 76/150 reads (51%) | catalogued as rs762115034; called by mutect2, varscan2
- METTL25 | c.1586T>A p.I529N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as rs1410419115, COSV50258953; called by muse, mutect2, varscan2
- MICAL2 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.044); catalogued as rs763464953, COSV56319816; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MMP25 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs143925847, COSV60678875; called by muse, mutect2, varscan2
- MORN1 | c.747C>T p.S249= | Splice Region (SNP) | VAF 69/161 reads (43%) | catalogued as rs751372454, COSV101047542; called by muse, mutect2, varscan2
- MPO | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 240/505 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761949874, COSV56561209; called by muse, mutect2, varscan2
- MRC2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 147/291 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs546895407, COSV57636441; called by muse, mutect2, varscan2
- MRE11 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs767097795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRM2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54247956; called by muse, mutect2, varscan2
- MROH8 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs769537714, COSV54117943; called by muse, mutect2, varscan2
- MRPS11 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 102/187 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs762797699; called by muse, mutect2, varscan2
- MTERF1 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs765277402, COSV61098197; called by muse, mutect2
- MUC16 | c.34094C>T p.T11365I | Missense Mutation (SNP) | VAF 127/270 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs777642205; called by muse, mutect2, varscan2
- MUC16 | c.24074A>G p.N8025S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1315996302, COSV67469440; called by muse, mutect2
- MUC17 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1164758470; called by muse, mutect2, varscan2
- MUC17 | c.5107G>C p.A1703P | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV60301305; called by muse, mutect2, varscan2
- MVK | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 295/718 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372166675; called by muse, varscan2
- MYOG | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as rs200354483, COSV54095180; called by muse, mutect2, varscan2
- MYOM3 | c.4207G>T p.G1403C | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773501383, COSV58391370, COSV58399053; called by muse, mutect2, varscan2
- NAGA | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 41/584 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs751220469; called by muse, mutect2
- NCAN | c.3836G>A p.R1279Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.336); catalogued as rs780098305; called by muse, mutect2, varscan2
- NCAPG2 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 140/331 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs527840789; called by muse, mutect2, varscan2
- NDUFA7 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as COSV56847732; called by muse, mutect2, varscan2
- NET1 | c.941G>A p.R314H (on ENST00000355029 / NM_001047160.3; = p.R260H on NM_005863.5) | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1205204380; called by muse, mutect2, varscan2
- NEU1 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 31/488 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1319757982; called by muse, mutect2
- NEXMIF | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50025295; called by muse, mutect2, varscan2
- NIBAN2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs762563150, COSV64825334; called by muse, mutect2, varscan2
- NIPBL | c.7801A>G p.M2601V | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs759275114; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 57/62 reads (92%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX1-1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1469500275; called by muse, mutect2, varscan2
- NMUR2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369018357, COSV54916843; called by muse, mutect2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 25/77 reads (32%) | catalogued as rs765400964; called by mutect2, pindel, varscan2
- NOLC1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs141424326; called by muse, mutect2, varscan2
- NR4A3 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 115/116 reads (99%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV58243212; called by muse, mutect2, varscan2
- NSRP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs572953048, COSV55936160; called by muse, mutect2, varscan2
- NT5DC3 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs758485823; called by muse, mutect2, varscan2
- NTRK3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201426743, COSV58111825; called by muse, mutect2, varscan2
- NTSR1 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 203/356 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368494260; called by muse, mutect2, varscan2
- NUMBL | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.755); catalogued as rs1192526014; called by muse, mutect2, varscan2
- OBSL1 | c.4583G>A p.R1528H | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759240898, COSV54705958; called by muse, mutect2, varscan2
- OLA1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375033952, COSV52969227; called by muse, mutect2, varscan2
- OPLAH | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 173/612 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1554757941, COSV70677818; called by muse, mutect2, varscan2
- OR10G8 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV70908170; called by muse, mutect2
- OR10H3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs778942345, COSV59943941; called by muse, mutect2, varscan2
- OR10T2 | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57780033; called by muse, mutect2, varscan2
- OR1C1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372819870, COSV101376227; called by muse, mutect2, varscan2
- OR2A4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 111/455 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59575638; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 65/245 reads (27%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR51E1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.699); catalogued as rs370898634, COSV67809759; called by muse, mutect2, varscan2
- OR51E1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200993659, COSV67810326; called by muse, mutect2, varscan2
- OR5H2 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100788702, COSV62350300; called by muse, mutect2, varscan2
- P4HA2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs147398523, COSV51324938; called by muse, mutect2, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, varscan2
- PCDHGA6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1415388106, COSV53989482; called by muse, mutect2, varscan2
- PCDHGA9 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs199517824; called by muse, mutect2, varscan2
- PDE6B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs182545478; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 100/239 reads (42%) | catalogued as rs747131399; called by mutect2, varscan2
- PER1 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753045671; called by muse, mutect2, varscan2
- PEX2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259658159; called by muse, mutect2
- PGAM5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs144537165; called by muse, mutect2
- PGLS | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1381699018; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 196/282 reads (70%) | catalogued as COSV53054111, COSV53054694; called by mutect2, pindel, varscan2
- PIP5K1C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs377291771, COSV58950241; called by muse, mutect2, varscan2
- PLD3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 168/379 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1246045495; called by mutect2, varscan2
- PLD5 | c.1121G>A p.R374Q (on ENST00000442594; = p.R312Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV59163972; called by muse, mutect2, varscan2
- PLEKHM3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 39/71 reads (55%) | catalogued as rs1416993669, COSV66815589; called by muse, mutect2, varscan2
- PLXNA3 | c.4471G>A p.A1491T | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63753112; called by muse, mutect2
- PLXNB3 | c.4522C>T p.R1508W | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62802061; called by muse, mutect2
- POLE | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 223/434 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs748522633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121 | c.1589C>T p.S530L (on ENST00000434423; = p.S265L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1206524450; called by mutect2, varscan2
- PPEF2 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99714719; called by muse, mutect2, varscan2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, mutect2, varscan2
- PPP3CA | c.230del p.N77Ifs*22 | Frame Shift Del (DEL) | VAF 56/124 reads (45%) | catalogued as rs1250808026; called by mutect2, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 108/240 reads (45%) | catalogued as rs766639242; called by mutect2, varscan2
- PRB4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 130/672 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as COSV54398610; called by muse, mutect2, varscan2
- PRDM16 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 92/139 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1407647352, COSV54605049, COSV54606419; called by muse, mutect2, varscan2
- PRDM9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 193/406 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs112157044; called by muse, mutect2, varscan2
- PRG4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 220/437 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs369769286, COSV66624843; called by muse, mutect2, varscan2
- PRKDC | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs772980444; called by muse, mutect2, varscan2
- PRKX | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1348033937; called by muse, mutect2, varscan2
- PROS1 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs373336653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1374775160, COSV99800417; called by muse, mutect2, varscan2
- PRPF3 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs201590000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR5 | c.317A>G p.Y106C (on ENST00000336985 / NM_181333.4; = p.Y97C on NM_015366.4) | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs1056779456; called by muse, mutect2
- PRR5 | c.494C>T p.A165V (on ENST00000336985 / NM_181333.4; = p.A156V on NM_015366.4) | Missense Mutation (SNP) | VAF 150/284 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs572406576; called by muse, mutect2, varscan2
- PRSS38 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs373887552; called by muse, mutect2, varscan2
- PUM2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV100163837, COSV57580987; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 101/342 reads (30%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- PWWP2B | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs965289685; called by muse, mutect2, varscan2
- PYHIN1 | c.1048del p.T350Qfs*6 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | catalogued as COSV63722536; called by mutect2, pindel, varscan2
- RAB11FIP1 | c.37del p.A13Pfs*10 | Frame Shift Del (DEL) | VAF 62/122 reads (51%) | catalogued as rs35243840; called by mutect2, varscan2
- RANBP2 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 162/384 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs978251652; called by muse, mutect2, varscan2
- RASGRP4 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 82/180 reads (46%) | catalogued as rs766578361, COSV99498370; called by muse, mutect2, varscan2
- RBFA | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs139845183; called by muse, mutect2, varscan2
- RBM10 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 295/632 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs868977796; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 65/67 reads (97%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374309282; called by muse, varscan2
- RBMXL3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1385235583; called by muse, mutect2, varscan2
- REPIN1 | c.1116dup p.S373Lfs*228 | Frame Shift Ins (INS) | VAF 29/120 reads (24%) | catalogued as rs759247453; called by mutect2, varscan2
- REPIN1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213016608; called by muse, varscan2
- RFESD | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as rs1213739059; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 34/72 reads (47%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS3 | c.1336G>A p.A446T (on ENST00000350696 / NM_001282923.2; = p.A334T on NM_017790.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1481532136; called by muse, mutect2, varscan2
- RILPL1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 168/319 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246793683; called by muse, mutect2, varscan2
- RNF213 | c.12949C>T p.R4317W | Missense Mutation (SNP) | VAF 184/402 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs759256018, COSV60407022; called by muse, mutect2, varscan2
- ROS1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 131/217 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs771282907; called by muse, mutect2, varscan2
- RP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 167/309 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369804244, COSV55114432; called by muse, mutect2, varscan2
- RP1 | c.2572del p.I858Yfs*37 | Frame Shift Del (DEL) | VAF 86/204 reads (42%) | catalogued as rs1214953601; called by mutect2, pindel, varscan2
- RP1L1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 173/175 reads (99%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1187441272, COSV66754347; called by muse, mutect2, varscan2
- RP1L1 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1400852717; called by muse, mutect2, varscan2
- RPP30 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.818); catalogued as rs137907824; called by muse, mutect2, varscan2
- RPRD2 | c.4048G>T p.G1350W | Missense Mutation (SNP) | VAF 124/211 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV64818724; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- RRP1 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 188/388 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs749236769; called by muse, varscan2
- RSPH10B | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs749914563; called by mutect2, varscan2
- RXFP1 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 121/265 reads (46%) | catalogued as rs200071060, COSV57055994; called by muse, mutect2, varscan2
- RYR1 | c.2079del p.Y694Tfs*36 | Frame Shift Del (DEL) | VAF 110/278 reads (40%) | catalogued as rs1568451501; called by mutect2, pindel, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 189/462 reads (41%) | catalogued as rs753320334; called by mutect2, varscan2
- SCAF1 | c.3540dup p.T1181Hfs*10 | Frame Shift Ins (INS) | VAF 46/93 reads (49%) | catalogued as rs769836700; called by mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCARF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 139/154 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867533840, COSV53958347, COSV53961566; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs765136101; called by mutect2, varscan2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 248/586 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2, varscan2
- SEC16A | c.5488G>A p.A1830T | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs761024052; called by muse, mutect2, varscan2
- SERTAD2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs772856400, COSV57641417; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 47/101 reads (47%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 41/129 reads (32%) | catalogued as rs70950549; called by mutect2, pindel, varscan2
- SH3BP5L | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs759575065; called by muse, mutect2, varscan2
- SH3RF3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451660266; called by muse, mutect2, varscan2
- SHANK1 | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1469441882; called by muse, varscan2
- SHANK3 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 183/556 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs575384100; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 82/168 reads (49%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHROOM3 | c.3193G>A p.G1065S | Missense Mutation (SNP) | VAF 229/561 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs775439655; called by muse, mutect2, varscan2
- SIAH3 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 166/343 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs750047881, COSV68552598; called by muse, mutect2, varscan2
- SKOR2 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV68550018; called by muse, mutect2, varscan2
- SLC15A1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs764483622, COSV64732066; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 138/270 reads (51%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 99/232 reads (43%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC27A3 | c.1636C>T p.P546S (on ENST00000271857; = p.P418S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1303528906; called by muse, mutect2, varscan2
- SLC2A7 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773308377, COSV68901454; called by muse, mutect2, varscan2
- SLC49A3 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 106/217 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs747020127, COSV59141639; called by muse, mutect2, varscan2
- SLC5A10 | c.1213G>A p.G405S (on ENST00000395645 / NM_001042450.4; = p.G421S on NM_152351.5) | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780119794; called by muse, mutect2, varscan2
- SLC5A11 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs368113331; called by muse, mutect2, varscan2
- SLC9C1 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1454329029; called by muse, mutect2, varscan2
- SLITRK6 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs762216866, COSV101233227; called by muse, mutect2, varscan2
- SMG1 | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1248193781, COSV67173781; called by muse, mutect2, varscan2
- SNTA1 | c.583del p.L195Ffs*23 | Frame Shift Del (DEL) | VAF 140/331 reads (42%) | catalogued as rs1443071118; called by mutect2, pindel, varscan2
- SNTB2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 208/414 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs758452589; called by muse, varscan2
- SOGA3 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775544839, COSV64106238; called by muse, mutect2, varscan2
- SORBS2 | c.2506C>T p.R836C (on ENST00000284776 / NM_021069.5; = p.R402C on NM_003603.6) | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs756993379; called by muse, mutect2, varscan2
- SORCS1 | c.558+2del p.X186_splice | Splice Site (DEL) | VAF 37/76 reads (49%) | catalogued as COSV53901348; called by mutect2, pindel, varscan2
- SOS2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV53566519; called by muse, mutect2, varscan2
- SOX1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as rs1465709458; called by muse, mutect2, varscan2
- SOX10 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 147/389 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100329862; called by muse, mutect2, varscan2
- SP5 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 134/214 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs767878015; called by muse, mutect2, varscan2
- SPARCL1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805981; called by muse, mutect2, varscan2
- SPATA31E1 | c.1589dup p.V531Cfs*13 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs758549558; called by mutect2, pindel, varscan2
- SPDEF | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 115/282 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775855317; called by muse, mutect2, varscan2
- SPHK2 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760049391; called by muse, mutect2, varscan2
- SPHKAP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60869857; called by muse, mutect2, varscan2
- SPTBN1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1209463186; called by muse, mutect2
- SRC | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62440190; called by muse, mutect2, varscan2
- SREK1IP1 | c.407del p.K136Rfs*22 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | catalogued as rs772485731; called by mutect2, pindel, varscan2
- SRGAP1 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 117/228 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs202173847; called by muse, mutect2, varscan2
- SRP68 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222515803; called by muse, mutect2, varscan2
- ST3GAL6 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV54585976; called by muse, mutect2, varscan2
- STIM2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs201149830, COSV99402981; called by muse, mutect2, varscan2
- STRIP1 | c.1705C>A p.R569S | Missense Mutation (SNP) | VAF 145/255 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874020; called by muse, mutect2, varscan2
- STRN4 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs371804979; called by muse, mutect2
- SUGCT | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781200920, COSV59343951; called by muse, mutect2, varscan2
- SUPT6H | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs775521641; called by muse, mutect2, varscan2
- SYCP2L | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs370377149; called by muse, mutect2, varscan2
- SYNE1 | c.24283C>T p.R8095C (on ENST00000367255 / NM_182961.4; = p.R8024C on NM_033071.3) | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200118773, COSV54942400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNGAP1 | c.3929C>T p.T1310M | Missense Mutation (SNP) | VAF 226/428 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs796430835, COSV99538062; called by muse, mutect2, varscan2
- TAOK1 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs771144246; called by muse, mutect2
- TAOK2 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779224250; called by muse, mutect2, varscan2
- TAS1R1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs530483330; called by muse, mutect2, varscan2
- TAS2R9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs756576629, COSV53688628; called by muse, mutect2, varscan2
- TBC1D17 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV55581042; called by muse, mutect2, varscan2
- TBXAS1 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 223/548 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs78666490, COSV54946635; called by muse, mutect2, varscan2
- TCHH | c.3069dup p.D1024Rfs*194 | Frame Shift Ins (INS) | VAF 130/301 reads (43%) | catalogued as rs1298090051; called by mutect2, pindel, varscan2
- TCHHL1 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV64285813; called by muse, mutect2, varscan2
- TCIRG1 | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 54/677 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs779330162; called by muse, mutect2
- TDRD5 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99675208; called by muse, mutect2, varscan2
- TEX43 | c.241_242del p.L81Vfs*6 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs779521055; called by pindel, varscan2
- TFDP3 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.556); catalogued as rs777030815, COSV59536621; called by muse, mutect2, varscan2
- TFPI2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as rs778950207; called by muse, mutect2, varscan2
- THBS1 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1350969818; called by muse, varscan2
- THBS3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772718514, COSV64248425; called by muse, mutect2
- THSD7B | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370266523; called by muse, mutect2, varscan2
- TIAM1 | c.4425dup p.G1476Rfs*6 | Frame Shift Ins (INS) | VAF 126/278 reads (45%) | catalogued as rs757091901; called by mutect2, varscan2
- TIAM1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758452455, COSV54542399; called by muse, mutect2, varscan2
- TIPARP | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs150068199; called by muse, mutect2, varscan2
- TLE2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs776121050; called by muse, mutect2, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 51/131 reads (39%) | catalogued as rs779826427; called by pindel, varscan2
- TLL1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99286821; called by muse, mutect2, varscan2
- TMCC2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 202/396 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1182470181; called by muse, mutect2, varscan2
- TMEM130 | c.804-1G>A p.X268_splice | Splice Site (SNP) | VAF 43/84 reads (51%) | catalogued as rs782243837; called by muse, mutect2, varscan2
- TMEM151A | c.1173dup p.A392Rfs*53 | Frame Shift Ins (INS) | VAF 102/302 reads (34%) | catalogued as rs1158034577; called by mutect2, pindel, varscan2
- TMEM201 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 148/268 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928354065, COSV61160846; called by muse, mutect2, varscan2
- TMEM54 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368310171; called by muse, mutect2, varscan2
- TMPRSS9 | c.2800C>T p.R934C (on ENST00000648592; = p.R900C on NM_182973.2) | Missense Mutation (SNP) | VAF 209/405 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs760660660, COSV53115519; called by muse, mutect2, varscan2
- TNFSF12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs758038102, COSV53434011; called by muse, mutect2, varscan2
- TNIP2 | c.657C>T p.H219= | Splice Region (SNP) | VAF 65/149 reads (44%) | catalogued as rs758835523; called by muse, mutect2, varscan2
- TNIP2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 203/344 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201862092, COSV59569770; called by muse, mutect2, varscan2
- TNPO2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369773308; called by muse, mutect2, varscan2
- TP53I11 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs762010357; called by muse, mutect2, varscan2
- TP53TG5 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs567269564; called by muse, mutect2, varscan2
- TRABD | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1305918751; called by muse, mutect2, varscan2
- TRAC | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750169372; called by muse, mutect2, varscan2
- TRAF2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs755436517, COSV56040676; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 114/268 reads (43%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2, varscan2
- TRIM32 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763720824, COSV100525687; called by muse, mutect2, varscan2
- TRIM56 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs199890101, COSV60161217; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 56/129 reads (43%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPA1 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as rs141174965, COSV100085577; called by muse, mutect2, varscan2
- TRPC6 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100723732; called by muse, mutect2, varscan2
- TRPV1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as rs375905892, COSV51518233; called by muse, mutect2, varscan2
- TSNARE1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs148280960, COSV56182027; called by muse, mutect2, varscan2
- TTC34 | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as rs1027234165; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 166/435 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147450804; called by muse, mutect2, varscan2
- TTN | c.72548G>A p.R24183H (on ENST00000591111; = p.R16759H on NM_003319.4) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | PolyPhen benign (0.007); catalogued as rs376051922; called by muse, mutect2, varscan2
- TTN | c.72323C>T p.A24108V (on ENST00000591111; = p.A16684V on NM_003319.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | PolyPhen benign (0.031); catalogued as COSV60190007; called by muse, mutect2, varscan2
- UBFD1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs752704984; called by muse, mutect2
- UNC5C | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV71658775, COSV71660832; called by muse, mutect2, varscan2
- UNC93B1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765034492; called by muse, mutect2, varscan2
- UNK | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454325757; called by muse, mutect2, varscan2
- UPK1B | c.697del p.V233Lfs*53 | Frame Shift Del (DEL) | VAF 20/205 reads (10%) | catalogued as rs763060314; called by mutect2, pindel
- USO1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752906782; called by muse, mutect2, varscan2
- VASP | c.551del p.P184Hfs*84 | Frame Shift Del (DEL) | VAF 43/104 reads (41%) | catalogued as rs762759767; called by mutect2, varscan2
- VIL1 | c.50del p.P17Rfs*73 | Frame Shift Del (DEL) | VAF 189/432 reads (44%) | catalogued as rs1452301630; called by mutect2, pindel, varscan2
- VIL1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs761167420; called by muse, mutect2, varscan2
- VN1R2 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as rs1394368853; called by muse, mutect2, varscan2
- VNN1 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 118/221 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100907702; called by muse, mutect2, varscan2
- VNN2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1204346828; called by muse, mutect2, varscan2
- VWDE | c.2100del p.K700Nfs*3 | Frame Shift Del (DEL) | VAF 106/214 reads (50%) | catalogued as rs781003137; called by mutect2, varscan2
- WDR33 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 159/378 reads (42%) | catalogued as rs1297033169, COSV59246969; called by muse, mutect2, varscan2
- WDR87 | c.3173A>C p.E1058A | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1333893820; called by muse, mutect2, varscan2
- WIPF1 | c.1079del p.P360Rfs*10 | Frame Shift Del (DEL) | VAF 106/270 reads (39%) | catalogued as rs1559146820; called by mutect2, pindel, varscan2
- WIPI1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 156/340 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs773822577; called by muse, mutect2, varscan2
- WIZ | c.3986G>A p.R1329Q (on ENST00000673675 / NM_001371589.1; = p.R234Q on NM_021241.3) | Missense Mutation (SNP) | VAF 130/226 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs766027386; called by muse, mutect2, varscan2
- WIZ | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 153/372 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568296331; called by muse, mutect2, varscan2
- WIZ | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs567582050; called by muse, mutect2, varscan2
- WRNIP1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764102921; called by muse, mutect2, varscan2
- WWC3 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1418681309, COSV66504998; called by muse, mutect2, varscan2
- ZBTB8B | c.281A>C p.N94T | Missense Mutation (SNP) | VAF 151/429 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999335701; called by muse, mutect2, varscan2
- ZC3H7B | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 436/773 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as rs989258774; called by muse, mutect2, varscan2
- ZDHHC12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 111/112 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199869993, COSV99403583; called by muse, mutect2, varscan2
- ZFAT | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 134/256 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755233371, COSV64741530; called by muse, mutect2, varscan2
- ZFAT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 121/203 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747833185, COSV64738099; called by muse, mutect2, varscan2
- ZFP90 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 81/139 reads (58%) | catalogued as rs776065123, COSV101238714; called by muse, mutect2, varscan2
- ZFP91 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60158747; called by muse, mutect2, varscan2
- ZFPM2 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 197/536 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs776822472, COSV65873600; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 71/153 reads (46%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/197 reads (12%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF16 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773234511, COSV52764628; called by muse, mutect2, varscan2
- ZNF28 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as COSV60425778; called by muse, mutect2, varscan2
- ZNF311 | c.970del p.T324Pfs*83 | Frame Shift Del (DEL) | VAF 124/302 reads (41%) | catalogued as COSV65853064; called by mutect2, pindel, varscan2
- ZNF324 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395574827; called by muse, mutect2, varscan2
- ZNF354A | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59985411; called by muse, mutect2, varscan2
- ZNF493 | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV62751319; called by muse, mutect2, varscan2
- ZNF496 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.962); catalogued as rs779568946; called by muse, mutect2
- ZNF506 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | catalogued as rs1409120867; called by mutect2, varscan2
- ZNF575 | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 216/400 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs1198734395, COSV58564643; called by muse, mutect2, varscan2
- ZNF585A | c.1360C>A p.H454N (on ENST00000292841 / NM_001288800.2; = p.H399N on NM_152655.3) | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.978); catalogued as COSV99493318, COSV99493700; called by muse, mutect2, varscan2
- ZNF644 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 205/556 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61348605; called by muse, mutect2, varscan2
- ZNF776 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 56/107 reads (52%) | catalogued as rs778356531, COSV100414236, COSV57815394; called by muse, mutect2, varscan2
- ZNF777 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 172/440 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV56098169; called by muse, mutect2, varscan2
- ZNF835 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 251/510 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs774840356, COSV73379453, COSV73379652; called by muse, varscan2
- ZNF850 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748702950, COSV101648599; called by muse, mutect2, varscan2
- ZNF878 | c.507del p.K169Nfs*44 | Frame Shift Del (DEL) | VAF 94/384 reads (24%) | catalogued as rs773648883, COSV72155908; called by pindel, varscan2
- ZSCAN10 | c.1109C>T p.T370I (on ENST00000252463; = p.T425I on NM_032805.3) | Missense Mutation (SNP) | VAF 114/219 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1374878211; called by muse, mutect2, varscan2
- ZSWIM1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1225498674; called by muse, mutect2
- AASS | c.913T>C p.C305R | Missense Mutation (SNP) | VAF 41/495 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ABCC3 | c.1817T>G p.L606R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.2483A>G p.Q828R | Missense Mutation (SNP) | VAF 197/511 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ABCD3 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 161/285 reads (56%) | called by muse, mutect2, varscan2
- ABCG8 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 302/563 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ABI3BP | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 20/373 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ABTB1 | c.1088G>A p.G363D (on ENST00000232744 / NM_172027.3; = p.G221D on NM_032548.3) | Missense Mutation (SNP) | VAF 154/417 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AC004593.2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 119/228 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACOX3 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ACSM2A | c.236T>C p.L79S | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- ACTR1A | c.85del p.Q29Rfs*82 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, pindel, varscan2
- ADAM32 | c.209del p.L70* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- ADAMTS9 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCY1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADCY3 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | called by mutect2, pindel, varscan2
- ADGRA1 | c.1667del p.N556Tfs*68 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel
- ADGRG4 | c.8922del p.F2974Lfs*15 | Frame Shift Del (DEL) | VAF 13/21 reads (62%) | called by mutect2, varscan2
- AFF3 | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 164/373 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP1 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 148/293 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AGAP4 | c.1601del p.K534Sfs*59 | Frame Shift Del (DEL) | VAF 108/581 reads (19%) | called by pindel, varscan2
- AK7 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH7A1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ALG10B | c.438dup p.N147* | Frame Shift Ins (INS) | VAF 114/128 reads (89%) | called by mutect2, varscan2
- AMBRA1 | c.2073-2A>G p.X691_splice (on ENST00000458649 / NM_001367468.1; = p.X601_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- AMDHD2 | c.1082C>A p.P361H (on ENST00000293971 / NM_001330449.2; = p.P391H on NM_015944.4) | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AMMECR1 | c.220del p.Q74Rfs*89 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- AMOTL2 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANAPC5 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 128/191 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ANO2 | c.2552del p.F851Sfs*6 (on ENST00000356134 / NM_001278597.3; = p.F855Sfs*6 on NM_001278596.3) | Frame Shift Del (DEL) | VAF 35/236 reads (15%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.044); called by muse, mutect2
- APBB2 | c.1322T>C p.V441A (on ENST00000295974 / NM_001166050.2; = p.V442A on NM_004307.2) | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AQP3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 194/207 reads (94%) | called by muse, mutect2, varscan2
- AQP6 | c.343del p.A115Lfs*37 | Frame Shift Del (DEL) | VAF 142/159 reads (89%) | called by mutect2, varscan2
- AREL1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 115/201 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ARFGEF1 | c.1376T>C p.L459S | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARHGAP5 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARHGEF12 | c.3668G>T p.G1223V | Missense Mutation (SNP) | VAF 133/307 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARID2 | c.4451_4452del p.I1484Sfs*18 | Frame Shift Del (DEL) | VAF 99/133 reads (74%) | called by mutect2, pindel, varscan2
- ARID4B | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARL13B | c.543del p.G182Afs*16 (on ENST00000394222 / NM_001174150.2; = p.G75Afs*16 on NM_144996.4) | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | called by mutect2, varscan2
- ARMCX1 | c.1256del p.F419Sfs*16 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- ARPIN | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 49/118 reads (42%) | called by mutect2, pindel, varscan2
- ASTE1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A5 | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 225/592 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP2A1 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 225/516 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP5PD | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ATP6V0D1 | c.854del p.P285Lfs*15 | Frame Shift Del (DEL) | VAF 171/442 reads (39%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 159/347 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- AWAT1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 119/218 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCKDHB | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCOR | c.3462G>T p.E1154D | Missense Mutation (SNP) | VAF 279/535 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BHLHA15 | c.428del p.E143Gfs*? (on ENST00000314018; = p.E143Gfs*80 on NM_177455.4) | Frame Shift Del (DEL) | VAF 132/373 reads (35%) | called by pindel, varscan2
- BMI1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- C11orf86 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C14orf180 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- C15orf65 | c.227del p.F76Sfs*27 | Frame Shift Del (DEL) | VAF 91/245 reads (37%) | called by mutect2, pindel, varscan2
- C1QTNF4 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- C2CD6 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.349); called by muse, mutect2
- C5orf52 | c.383del p.K128Sfs*3 | Frame Shift Del (DEL) | VAF 82/173 reads (47%) | called by mutect2, varscan2
- CA11 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- CABP1 | c.668G>A p.R223Q (on ENST00000316803 / NM_001033677.1; = p.R20Q on NM_004276.5) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNG3 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 99/178 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CALM1 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- CAMSAP3 | c.2690A>G p.D897G | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CARMIL2 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CASP2 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 312/704 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CASP9 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 272/461 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC114 | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 16/315 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- CCDC141 | c.1906del p.E636Rfs*5 | Frame Shift Del (DEL) | VAF 53/128 reads (41%) | called by mutect2, pindel, varscan2
- CCDC168 | c.17856del p.K5952Nfs*2 | Frame Shift Del (DEL) | VAF 50/144 reads (35%) | called by mutect2, pindel, varscan2
- CCDC168 | c.13675G>A p.E4559K | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CCDC168 | c.9262_9265del p.L3088Vfs*18 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, varscan2
- CCDC168 | c.5485C>A p.Q1829K | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CCDC74A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 157/597 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CCDC8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 261/578 reads (45%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, varscan2
- CCER2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCP110 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCR1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD58 | c.174dup p.Q59Tfs*4 | Frame Shift Ins (INS) | VAF 58/148 reads (39%) | called by mutect2, pindel, varscan2
- CD63 | c.331-2A>G p.X111_splice | Splice Site (SNP) | VAF 118/118 reads (100%) | called by muse, mutect2, varscan2
- CDK12 | c.3810del p.G1271Dfs*23 (on ENST00000447079 / NM_016507.4; = p.G1262Dfs*23 on NM_015083.3) | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | called by pindel, varscan2
- CDV3 | c.272_273del p.K91Rfs*3 | Frame Shift Del (DEL) | VAF 54/130 reads (42%) | called by mutect2, pindel, varscan2
- CENPH | c.314+1G>A p.X105_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- CENPI | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, varscan2
- CEP131 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2
- CEP63 | c.53del p.L18* | Frame Shift Del (DEL) | VAF 84/199 reads (42%) | called by mutect2, pindel, varscan2
- CFAP73 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CFL1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHERP | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHMP1B | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 219/454 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CHRM5 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRNA4 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 208/478 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNB1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 338/338 reads (100%) | called by muse, mutect2, varscan2
- CHST2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CLDN11 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 273/771 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLP1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLPTM1L | c.616del p.T206Pfs*17 | Frame Shift Del (DEL) | VAF 172/432 reads (40%) | called by mutect2, pindel, varscan2
- CLSPN | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CLSPN | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLTA | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNGA4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 201/512 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CNTNAP5 | c.3110dup p.E1038Gfs*6 | Frame Shift Ins (INS) | VAF 40/390 reads (10%) | called by mutect2, pindel, varscan2
- CNTRL | c.6747G>T p.K2249N | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL12A1 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- COL5A2 | c.4421T>A p.I1474N | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL8A1 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A1 | c.811_812insA p.P271Hfs*3 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- COLGALT2 | c.1555A>C p.M519L | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2
- COMMD5 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- COMTD1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- CORO6 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 130/226 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by mutect2, varscan2
- CPE | c.1417A>T p.T473S | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CPSF1 | c.3581G>A p.S1194N | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CROCC2 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CSRNP3 | c.1259A>C p.E420A | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CSTF1 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTAGE9 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 293/800 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- CTRB2 | c.53-3dup | Splice Region (INS) | VAF 53/125 reads (42%) | called by mutect2, pindel, varscan2
- CX3CL1 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CYP4F8 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DAAM2 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCAF12L2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDIT3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- DDX10 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DEFB118 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2
- DGCR2 | c.1073_1076del p.F358Sfs*24 | Frame Shift Del (DEL) | VAF 157/318 reads (49%) | called by pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 116/285 reads (41%) | called by mutect2, pindel, varscan2
- DLC1 | c.1897A>G p.N633D (on ENST00000276297 / NM_001348081.2; = p.N196D on NM_006094.5) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DLG2 | c.1275C>G p.H425Q | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DMD | c.10277del p.P3426Lfs*19 | Frame Shift Del (DEL) | VAF 121/279 reads (43%) | called by mutect2, pindel, varscan2
- DMRTC2 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- DNAH11 | c.6680G>A p.G2227D | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | called by mutect2, pindel, varscan2
- DNAH6 | c.3216del p.S1073Hfs*8 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | called by mutect2, pindel, varscan2
- DOK7 | c.568del p.E190Sfs*56 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by mutect2, pindel, varscan2
- DPP9 | c.2476G>A p.A826T (on ENST00000598800; = p.A855T on NM_139159.5) | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, varscan2
- DUSP8 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 143/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- E2F7 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 133/353 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1D | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 151/254 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EEPD1 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFEMP1 | c.1301dup p.N434Kfs*87 | Frame Shift Ins (INS) | VAF 101/286 reads (35%) | called by mutect2, pindel, varscan2
- EHBP1 | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EML6 | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ENTPD1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- EPG5 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- EPHA7 | c.1538del p.F513Sfs*23 | Frame Shift Del (DEL) | VAF 70/172 reads (41%) | called by mutect2, pindel, varscan2
- EPHA7 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- EPHX2 | c.548del p.L183Wfs*8 | Frame Shift Del (DEL) | VAF 13/139 reads (9%) | called by mutect2, pindel
- EPRS1 | c.3221A>G p.E1074G | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ERVH48-1 | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 54/593 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EYS | c.4160G>T p.R1387M | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- F7 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- FAAP100 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 101/195 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- FAAP20 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- FAM117B | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
963 further variants in this file (415 protein-altering or splice-affecting, 329 silent, 219 other) are not listed here.
